Somatic mutation profile of tumor specimen TARGET-30-PATINJ-01A (aliquot TARGET-30-PATINJ-01A-01D) from TARGET case TARGET-30-PATINJ, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 2.8 years (1,037 days).
Specimen TARGET-30-PATINJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3a256c8-b671-43d3-b611-9870e3cf6e1a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATINJ-10A (Blood Derived Normal), aliquot TARGET-30-PATINJ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ce1a056-e08a-4133-8dbe-bb83b1709be1

The open-access MAF lists 18 somatic variants for this specimen: 16 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 12, Silent 2, In Frame Del 1, Nonsense Mutation 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNOT4 | c.1629G>C p.G543= (on ENST00000315544 / NM_001190848.1; = p.G540= on NM_001008225.2) | Splice Region (SNP) | VAF 13/35 reads (37%) | catalogued as COSV59649481; called by muse, mutect2, varscan2
- DAB2 | c.2148G>T p.K716N | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57911982; called by muse, mutect2, varscan2
- EXTL1 | c.1667C>G p.A556G | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV65332070; called by muse, mutect2, varscan2
- HIVEP2 | c.1789G>T p.E597* | Nonsense Mutation (SNP) | VAF 32/101 reads (32%) | catalogued as COSV50005279; called by muse, mutect2, varscan2
- MUC17 | c.8887G>T p.A2963S | Missense Mutation (SNP) | VAF 123/380 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.095); catalogued as COSV100072374, COSV60278988; called by muse, mutect2, varscan2
- OR5M1 | c.907C>A p.Q303K | Missense Mutation (SNP) | VAF 65/245 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV73201939; called by muse, mutect2, varscan2
- PDE1C | c.1478del p.P493Rfs*204 (on ENST00000321453 / NM_001191059.3; = p.P493Rfs*160 on NM_005020.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 6/76 reads (8%) | catalogued as COSV58519866; called by mutect2, pindel
- POLE | c.1942G>A p.E648K | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs961415389, COSV57673151; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPARGC1A | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs781635737, COSV53523784; called by muse, mutect2, varscan2
- RNF43 | c.554G>T p.R185M | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV68456703; called by muse, mutect2, varscan2
- SMG9 | c.95C>G p.S32C | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV54213328; called by muse, mutect2, varscan2
- ADAMTS9 | c.2783C>A p.T928N | Missense Mutation (SNP) | VAF 10/239 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.146); called by muse, mutect2
- BNC2 | c.1914G>T p.M638I | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2
- CBLB | c.886_900del p.A296_V300del | In Frame Del (DEL) | VAF 18/43 reads (42%) | called by mutect2, pindel, varscan2
- ERN2 | c.1100C>A p.P367Q | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.358); called by muse, mutect2
- IGSF21 | c.962G>A p.C321Y | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- BBX | c.2013G>A p.K671= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV57877969; called by muse, mutect2, varscan2
- EVPL | c.4395G>C p.V1465= | Silent (SNP) | VAF 28/152 reads (18%) | catalogued as COSV101440970, COSV56906627; called by muse, mutect2, varscan2
